Somatic mutation profile of tumor specimen BA2110D (aliquot aq-BA2110D) from BEATAML1.0 case 2305, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.1 years (23,786 days).
Specimen BA2110D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf3acfe1-6f36-47d2-9e33-950fe1f83859.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2754D (Solid Tissue Normal), aliquot aq-BA2754D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10da57d5-e87e-4266-a5cf-ea8f14675ec4

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIAA1671 | c.2926C>T p.R976* | Nonsense Mutation (SNP) | VAF 21/168 reads (13%) | called by muse, mutect2, varscan2
- PTPN21 | c.1857G>T p.E619D | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZNF648 | c.1546G>T p.A516S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
